Somatic mutation profile of tumor specimen 74f7759a-279c-4098-b080-358900 (aliquot 74f7759a-279c-4098-b080-358900_D6_1) from CPTAC case 15CO002, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB.
Specimen 74f7759a-279c-4098-b080-358900: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a73f28e-0724-4f45-bfd0-48e801755d46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d98655bc-7db0-4301-bffc-a59a1d (Blood Derived Normal), aliquot d98655bc-7db0-4301-bffc-a59a1d_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aec370ff-1578-4047-85a4-e81f65d2c4a9

The open-access MAF lists 98 somatic variants for this specimen: 71 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 22, Nonsense Mutation 4, Frame Shift Ins 3, Intron 3, Frame Shift Del 2, Splice Region 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2138C>G p.S713* | Nonsense Mutation (SNP) | VAF 53/142 reads (37%) | catalogued as rs137854570, CM910032, COSV57327842, COSV99971722; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 66/181 reads (36%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 151/407 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS10 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 129/429 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.888); catalogued as rs199769798, COSV99546355; called by muse, mutect2, varscan2
- ALDH16A1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs536614905; called by muse, mutect2, varscan2
- ALDH9A1 | c.1454A>T p.K485M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs552075619; called by muse, mutect2, varscan2
- AMER1 | c.635del p.P212Lfs*70 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as COSV57663933; called by mutect2, pindel, varscan2
- ATAD2 | c.2981G>A p.R994K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54885114; called by muse, mutect2, varscan2
- BRAT1 | c.1892C>T p.T631M | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as rs763369342; called by muse, mutect2, varscan2
- C7orf31 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs753347848; called by mutect2, varscan2
- CDH4 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs764411029, COSV64665210; called by muse, mutect2, varscan2
- CDK5RAP2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs367746734; called by muse, mutect2, varscan2
- CNP | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 143/306 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1555643207; called by muse, mutect2, varscan2
- COA4 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs150976532; called by muse, mutect2, varscan2
- COL4A5 | c.3728C>T p.P1243L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs751503027, COSV60361960; called by muse, mutect2, varscan2
- CSMD2 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs775653058, COSV53887805; called by muse, mutect2, varscan2
- CYP11B1 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 212/650 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99454372; called by mutect2, varscan2
- GALNT14 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs778348392, COSV61105848; called by muse, mutect2, varscan2
- GRID2 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs754149861, COSV56218833; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs761911811; called by muse, mutect2
- LSAMP | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1399307120, COSV61294319; called by muse, mutect2, varscan2
- LTA4H | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.674); catalogued as rs138184255; called by muse, mutect2, varscan2
- MAP1B | c.1669G>A p.V557M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs374708245; called by muse, mutect2, varscan2
- MON1A | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 152/336 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754451998; called by muse, mutect2, varscan2
- MPO | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs1435800082; called by muse, mutect2, varscan2
- MUC16 | c.11658G>T p.M3886I | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV101200441, COSV67463193; called by muse, mutect2, varscan2
- MYH11 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 76/524 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401359617, COSV55554511; called by mutect2, varscan2
- MYO9B | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs766201555; called by muse, mutect2, varscan2
- NPTX2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs563276077, COSV99675175; called by muse, mutect2, varscan2
- OXTR | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV57480336; called by muse, mutect2
- PEX11G | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs1003026572; called by muse, mutect2
- PIGU | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs755704192, COSV54165019; called by muse, mutect2, varscan2
- PRR35 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs372578151, COSV53461764, COSV53462424; called by muse, mutect2, varscan2
- PYGB | c.1754T>C p.V585A | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV99404835; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as rs752293510; called by muse, mutect2, varscan2
- ROBO2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.094); catalogued as rs746150931, COSV100167830, COSV59898161; called by muse, mutect2
- SALL1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1223836455, COSV51758197; called by muse, mutect2, varscan2
- SGCB | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV67341000; called by muse, mutect2, varscan2
- SLC30A3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs771149305, COSV51985661, COSV51986814; called by muse, mutect2, varscan2
- SLITRK5 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61520512; called by muse, mutect2, varscan2
- SMCO1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs62410569, COSV58839140; called by muse, mutect2, varscan2
- STAC2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs181240828; called by muse, mutect2, varscan2
- TP53BP1 | c.4376G>A p.R1459H | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770333392, COSV99781158; called by muse, mutect2, varscan2
- WDR12 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs746259580, COSV99651030; called by muse, mutect2, varscan2
- ZNF483 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1462455547; called by muse, mutect2, varscan2
- ABCA2 | c.5423_5424insA p.S1809Qfs*200 (on ENST00000614293; = p.S1779Qfs*200 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/214 reads (13%) | called by mutect2, pindel*, varscan2
- ACTN4 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- CCN2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FAT2 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FLACC1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- GBP5 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR179 | c.7009_7010del p.Q2337Vfs*6 (on ENST00000621958; = p.Q2336Vfs*6 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- MAPK9 | c.289dup p.T97Nfs*18 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by pindel, varscan2
- MAST3 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- MROH9 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MRPL1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MRPL47 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NEMP2 | c.198A>G p.I66M | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.034); called by muse, mutect2
- OR10A5 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PLET1 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PREX1 | c.2734G>C p.V912L | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPRC | c.3331-3T>G | Splice Region (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- SHARPIN | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- TCF7L2 | c.1058C>G p.P353R (on ENST00000355995 / NM_001367943.1; = p.P330R on NM_030756.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR9 | c.2534A>T p.Y845F | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIR | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- TRPM2 | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 35/190 reads (18%) | called by muse, mutect2, varscan2
- TUBG1 | c.66G>C p.W22C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX4 | c.9604dup p.I3202Nfs*34 | Frame Shift Ins (INS) | VAF 48/136 reads (35%) | called by mutect2, varscan2
- ZNF398 | c.366C>A p.N122K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF711 | c.996A>T p.R332S | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ADIPOQ | c.180C>A p.G60= | Silent (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- ATG9B | c.888G>A p.L296= | Silent (SNP) | VAF 43/188 reads (23%) | catalogued as rs753676261; called by muse, mutect2, varscan2
- ATP1A4 | c.2292C>T p.I764= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as rs1310892260; called by muse, mutect2
- CCDC166 | c.210C>T p.R70= | Silent (SNP) | VAF 98/382 reads (26%) | catalogued as rs782664518; called by muse, mutect2, varscan2
- CDC14C | c.369C>T p.D123= (on ENST00000428251; = p.D16= on NM_152627.3) | Silent (SNP) | VAF 27/256 reads (11%) | catalogued as rs190940569; called by muse, mutect2, varscan2
- CGNL1 | c.3891C>T p.T1297= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs768320922; called by muse, mutect2, varscan2
- HLX | c.1374C>T p.G458= | Silent (SNP) | VAF 34/236 reads (14%) | catalogued as rs1427152229; called by muse, mutect2, varscan2
- HS3ST3A1 | c.648G>A p.T216= | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as rs367953318; called by muse, mutect2, varscan2
- IKZF1 | c.867C>T p.S289= | Silent (SNP) | VAF 40/173 reads (23%) | catalogued as rs776826728, COSV100498452; called by muse, mutect2, varscan2
- IRX4 | c.387G>A p.L129= | Silent (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- JPH2 | c.1401C>T p.R467= | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- KIAA1549L | c.5433C>T p.N1811= (on ENST00000321505; = p.N2108= on NM_012194.3) | Silent (SNP) | VAF 45/353 reads (13%) | catalogued as rs774771087, COSV58593792; called by muse, mutect2, varscan2
- LRRTM3 | c.418C>T p.L140= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as rs147373916; called by muse, mutect2, varscan2
- MAEA | c.597C>T p.S199= (on ENST00000303400 / NM_001017405.3; = p.S158= on NM_005882.5) | Silent (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- NOVA2 | c.726C>T p.A242= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1248774693; called by muse, mutect2
- PASD1 | c.768T>G p.V256= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100949565; called by muse, mutect2, varscan2
- POLA1 | c.2619C>T p.N873= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs1192650550; called by muse, mutect2, varscan2
- PRLHR | c.483C>T p.V161= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as rs745837923, COSV53303163; called by muse, mutect2, varscan2
- RAB40A | c.90C>A p.I30= | Silent (SNP) | VAF 46/498 reads (9%) | catalogued as COSV58490746; called by muse, mutect2
- SLC41A1 | c.1245C>T p.L415= | Silent (SNP) | VAF 71/222 reads (32%) | catalogued as rs541250820; called by muse, mutect2, varscan2
- TEX37 | c.111G>A p.T37= | Silent (SNP) | VAF 15/155 reads (10%) | catalogued as rs370424706; called by muse, mutect2, varscan2
- TTN | c.36120G>C p.V12040= (on ENST00000591111; = p.V4616= on NM_003319.4) | Silent (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516164 G>A | 5'Flank (SNP) | VAF 73/512 reads (14%) | called by muse, mutect2, varscan2
- PTGDS | c.331+71G>T | Intron (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- ROBO2 | c.*6G>T | 3'UTR (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- ROGDI | c.117+35G>A | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as rs1288891162; called by muse, mutect2, varscan2
- SETD6 | c.793-14C>T | Intron (SNP) | VAF 39/215 reads (18%) | called by muse, mutect2, varscan2
